Somatic mutation profile of tumor specimen TCGA-UE-A6QT-01A (aliquot TCGA-UE-A6QT-01A-12D-A32I-09) from TCGA case TCGA-UE-A6QT, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic liposarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 50.7 years (18,516 days).
Specimen TCGA-UE-A6QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f698e824-5fd9-4890-98d7-17ed86f0035a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UE-A6QT-10B (Blood Derived Normal), aliquot TCGA-UE-A6QT-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f74c511a-ad02-469b-9e80-01be1edfc68b

The open-access MAF lists 18 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 13, Silent 4, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137853294, CD135177, CM920603, COSV57295487; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS19 | c.3597A>T p.E1199D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV50789821, COSV99184202; called by muse, mutect2
- CRY2 | c.600G>C p.E200D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101314626, COSV69889201; called by muse, mutect2, varscan2
- DEAF1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.51); catalogued as rs371722695; called by muse, mutect2, varscan2
- MAGEC1 | c.3422C>T p.S1141F | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.831); catalogued as COSV53572241; called by muse, mutect2, varscan2
- MYO1A | c.327G>A p.E109= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as COSV100271353; called by muse, mutect2, varscan2
- NCKIPSD | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs906851991, COSV99584368; called by muse, mutect2
- PCDHA3 | c.1780G>A p.V594M | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV100793857; called by muse, mutect2
- RBP2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as rs765508653, COSV51673840; called by muse, mutect2, varscan2
- RP1L1 | c.4745G>A p.R1582Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as rs755207488, COSV66754394, COSV66754907; called by muse, mutect2, varscan2
- SELP | c.2382G>T p.L794F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV99741380; called by muse, mutect2, varscan2
- TNN | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs143132527, COSV99513359; called by mutect2, varscan2
- CPAMD8 | c.981G>A p.V327= (on ENST00000651564; = p.V280= on NM_015692.5) | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV52231135, COSV99359929; called by muse, mutect2, varscan2
- ENAM | c.1398T>C p.V466= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV101253395; called by muse, mutect2, varscan2
- FLNC | c.2577C>T p.I859= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100368977; called by muse, mutect2, varscan2
- SLC16A6 | c.804C>T p.V268= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100517449; called by muse, mutect2, varscan2
